Somatic mutation profile of tumor specimen TCGA-AO-A0JG-01A (aliquot TCGA-AO-A0JG-01A-31D-A099-09) from TCGA case TCGA-AO-A0JG, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 49.3 years (18,021 days).
Specimen TCGA-AO-A0JG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 886291ca-eb69-4f5c-a563-a0bada4dd2a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0JG-10A (Blood Derived Normal), aliquot TCGA-AO-A0JG-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71623e2c-3bfa-477b-adc1-7755d1c62873

The open-access MAF lists 15 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 14, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GNT9 | c.656G>A p.C219Y | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1387654179, COSV104374923; called by muse, mutect2
- BCO1 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99257860; called by muse, mutect2, varscan2
- CLCN3 | c.2106A>T p.R702S | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.805); catalogued as COSV100641683; called by muse, mutect2, varscan2
- HTATSF1 | c.1355G>T p.S452I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99511612; called by muse, mutect2
- KMT2C | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100071216; called by muse, mutect2, varscan2
- LRRC7 | c.3496T>C p.F1166L (on ENST00000651989 / NM_001370785.2; = p.F1133L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.719); catalogued as COSV99226357; called by muse, mutect2, varscan2
- NAGK | c.697T>C p.Y233H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99730584; called by muse, mutect2, varscan2
- OXCT2 | c.1414G>T p.V472L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100560260, COSV59593097; called by muse, mutect2, varscan2
- PIK3R1 | c.1218C>A p.N406K (on ENST00000521381 / NM_181523.3; = p.N136K on NM_181504.4) | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.414); catalogued as COSV99142898; called by muse, mutect2, varscan2
- QSER1 | c.607G>A p.A203T (on ENST00000399302; = p.A332T on NM_001076786.3) | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as COSV101234830; called by muse, mutect2, varscan2
- RANBP9 | c.712G>C p.G238R | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99163529; called by muse, varscan2
- SLC13A2 | c.1003C>A p.L335I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as COSV100120292; called by muse, mutect2, varscan2
- TMEM260 | c.165A>T p.E55D | Missense Mutation (SNP) | VAF 87/332 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99840273; called by muse, mutect2, varscan2
- UBE2Z | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.115); catalogued as COSV100711531; called by muse, mutect2, varscan2
- CTCFL | c.1344C>G p.R448= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99712528; called by muse, mutect2, varscan2
